Somatic mutation profile of tumor specimen TCGA-W3-A824-06A (aliquot TCGA-W3-A824-06A-21D-A34U-08) from TCGA case TCGA-W3-A824, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 67.3 years (24,592 days).
Specimen TCGA-W3-A824-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a76023d-dd9c-4c5b-b53b-564759db8032.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W3-A824-10A (Blood Derived Normal), aliquot TCGA-W3-A824-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/339b8cb7-693f-4931-bd46-c9b2d580423b

The open-access MAF lists 1,786 somatic variants for this specimen: 1,166 protein-altering or splice-affecting, 585 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,021, Silent 585, Nonsense Mutation 76, Frame Shift Del 25, Splice Region 19, Intron 16, Splice Site 16, RNA 12, Frame Shift Ins 4, In Frame Del 3, 3'UTR 3, 5'UTR 2.

Variants (750 of 1,786; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A1 | c.3371G>A p.G1124E | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1085307568, COSV101010913; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.10615C>T p.R3539C | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304504006, CM091938, COSV54205813; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 32/94 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 42/121 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PTEN | c.188del p.N63Tfs*36 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs1554897267, COSV64298134; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RAF1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs80338796, CM073301, COSV52574378, COSV52579821; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TPO | c.2421del p.C808Afs*24 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | catalogued as rs760307139, COSV100220194; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ZNF341 | c.1156C>T p.R386* (on ENST00000375200 / NM_001282935.1; = p.R379* on NM_032819.4) | Nonsense Mutation (SNP) | VAF 36/102 reads (35%) | catalogued as rs982121798, COSV100677583; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1355721856, COSV99255018; called by muse, mutect2, varscan2
- A2M | c.1841C>T p.S614L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs373637929, COSV59383530; called by muse, mutect2, varscan2
- A4GALT | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756072106, COSV99966568; called by muse, mutect2, varscan2
- AASS | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100741617; called by muse, mutect2, varscan2
- ABAT | c.1382-1G>A p.X461_splice | Splice Site (SNP) | VAF 54/121 reads (45%) | catalogued as COSV99190866; called by muse, mutect2, varscan2
- ABCA13 | c.5374G>A p.A1792T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as rs188043455; called by muse, mutect2, varscan2
- ABCA3 | c.3926C>T p.S1309F | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV57061578; called by muse, mutect2, varscan2
- ABCA6 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV52638525; called by muse, mutect2, varscan2
- ABCB1 | c.2470C>G p.Q824E | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as COSV99711866; called by muse, mutect2, varscan2
- ABCB10 | c.1695G>A p.W565* | Nonsense Mutation (SNP) | VAF 35/122 reads (29%) | catalogued as COSV100747828; called by muse, mutect2, varscan2
- ABCB9 | c.1172A>G p.Y391C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99757498; called by muse, mutect2, varscan2
- ABCC5 | c.1702C>T p.H568Y | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99656247; called by muse, mutect2, varscan2
- ABCC6 | c.3194C>T p.S1065F | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.882); catalogued as COSV99227895; called by muse, mutect2, varscan2
- ABCD4 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.71); catalogued as COSV100083950; called by muse, mutect2, varscan2
- ABLIM3 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.293); catalogued as rs1280322060, COSV100447962; called by muse, mutect2, varscan2
- ABO | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as rs782542998, COSV101505918; called by muse, mutect2, varscan2
- AC024598.1 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as rs1351143389, COSV67922776; called by muse, mutect2, varscan2
- AC109583.1 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58405239; called by muse, mutect2
- AC144573.1 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0); catalogued as rs868183081, COSV100294272; called by muse, mutect2, varscan2
- ACAN | c.4963G>A p.G1655R | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100716758; called by muse, mutect2, varscan2
- ACAN | c.6946G>A p.D2316N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100716759; called by muse, mutect2, varscan2
- ADAM11 | c.2268G>A p.W756* | Nonsense Mutation (SNP) | VAF 15/28 reads (54%) | catalogued as COSV99567025; called by muse, mutect2, varscan2
- ADAMTS18 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs775958686, COSV99270881; called by muse, mutect2, varscan2
- ADAMTS19 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99176187; called by muse, mutect2, varscan2
- ADAMTS19 | c.2381C>T p.S794L | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50736671; called by muse, mutect2, varscan2
- ADAMTS20 | c.4072C>T p.P1358S | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV101166012; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4671T>A p.C1557* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV101000402; called by muse, mutect2, varscan2
- ADCY3 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.338); catalogued as COSV53169564; called by muse, mutect2, varscan2
- ADCY4 | c.2502G>A p.M834I | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV60256490; called by muse, mutect2, varscan2
- ADCY4 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371404448; called by muse, mutect2, varscan2
- ADCY8 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 117/203 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.421); catalogued as COSV99650266; called by muse, mutect2, varscan2
- ADCY8 | c.1133T>A p.L378H | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV99650268; called by muse, mutect2, varscan2
- ADGRE1 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV51680447; called by muse, mutect2
- ADGRE3 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99505680; called by muse, mutect2, varscan2
- ADGRF3 | c.413C>T p.P138L (on ENST00000311519 / NM_001145168.1; = p.P79L on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.021); catalogued as COSV100274675; called by muse, mutect2, varscan2
- ADGRG4 | c.6400T>C p.S2134P | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99794090; called by muse, mutect2, varscan2
- ADGRL2 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV99586715; called by muse, mutect2, varscan2
- ADGRL4 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66064142; called by muse, mutect2, varscan2
- ADPGK | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100295101; called by muse, mutect2, varscan2
- AFF2 | c.3832G>A p.D1278N | Missense Mutation (SNP) | VAF 55/73 reads (75%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV99661353; called by muse, mutect2, varscan2
- AFF4 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 25/62 reads (40%) | catalogued as COSV99534471; called by muse, mutect2, varscan2
- AHCYL1 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100779327; called by muse, mutect2, varscan2
- AHNAK2 | c.3056C>T p.A1019V | Missense Mutation (SNP) | VAF 123/325 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as rs769666323, COSV100315089; called by muse, mutect2, varscan2
- AKNAD1 | c.1749G>A p.E583= | Splice Region (SNP) | VAF 7/25 reads (28%) | catalogued as rs768665987, COSV100645215; called by muse, mutect2, varscan2
- AKR1B10 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100610118, COSV62056186; called by muse, mutect2, varscan2
- AKT3 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as COSV99793875; called by muse, mutect2, varscan2
- AL358113.1 | c.3937C>T p.R1313* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as rs756017678, COSV61958851; called by muse, mutect2, varscan2
- ALAD | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99474492; called by muse, mutect2, varscan2
- ALDH1A2 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV99990201; called by muse, mutect2, varscan2
- ALDH1L1 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as rs13088615; called by muse, varscan2
- ALDH3A1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.577); catalogued as rs750383473, COSV56736817; called by muse, mutect2, varscan2
- ALDH9A1 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100699263; called by muse, mutect2, varscan2
- ALK | c.2044C>T p.H682Y | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as COSV101200844; called by muse, mutect2, varscan2
- ALKBH2 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99980058; called by muse, mutect2, varscan2
- ALPI | c.478A>C p.K160Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99785639; called by muse, mutect2, varscan2
- AMER3 | c.1794T>G p.D598E | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV100365879; called by muse, mutect2, varscan2
- ANGPTL1 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758492969, COSV99327909; called by muse, mutect2, varscan2
- ANKRD46 | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV100169865; called by muse, mutect2, varscan2
- ANO2 | c.25C>T p.P9S (on ENST00000356134 / NM_001278597.3; = p.P13S on NM_001278596.3) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); catalogued as COSV100499438; called by muse, mutect2, varscan2
- ANO4 | c.2492G>A p.R831Q (on ENST00000392977 / NM_001286615.2; = p.R796Q on NM_178826.4) | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.052); catalogued as rs868314489, COSV54590940; called by muse, varscan2
- ANO4 | c.2513G>A p.R838Q (on ENST00000392977 / NM_001286615.2; = p.R803Q on NM_178826.4) | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.202); catalogued as rs778005685, COSV54596564, COSV54598541; called by muse, varscan2
- AP3S1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as COSV100372568; called by muse, mutect2, varscan2
- APBA2 | c.2008C>T p.Q670* | Nonsense Mutation (SNP) | VAF 44/124 reads (35%) | catalogued as COSV101381805; called by muse, mutect2, varscan2
- ARHGAP22 | c.740G>A p.R247K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs759834785, COSV50944061; called by muse, mutect2, varscan2
- ARHGAP31 | c.2951C>A p.S984Y | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99956427, COSV99957110; called by muse, mutect2, varscan2
- ARHGAP6 | c.2207G>A p.G736E (on ENST00000337414 / NM_013427.3; = p.G533E on NM_013423.3) | Missense Mutation (SNP) | VAF 62/74 reads (84%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs773244581, COSV57295733, COSV57305693; called by muse, mutect2, varscan2
- ARHGEF10 | c.3989C>T p.S1330L (on ENST00000398564; = p.S1305L on NM_014629.4) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs144142470; called by muse, mutect2, varscan2
- ARHGEF12 | c.1276C>T p.H426Y | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as COSV100754552; called by muse, mutect2, varscan2
- ARID4A | c.301T>G p.L101V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100793925; called by muse, mutect2, varscan2
- ARID5A | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100673510; called by muse, mutect2, varscan2
- ARID5A | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs768451723, COSV100673511; called by muse, mutect2, varscan2
- ARL10 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.6); catalogued as COSV100118941; called by muse, varscan2
- ARMH3 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100898741; called by muse, mutect2, varscan2
- ARMS2 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.027); catalogued as COSV101600724, COSV73306982; called by muse, mutect2, varscan2
- ARSD | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 20/22 reads (91%) | catalogued as rs777983306, COSV54202087, COSV99471897; called by muse, mutect2, varscan2
- ASB15 | c.1440G>A p.P480= | Splice Region (SNP) | VAF 37/85 reads (44%) | catalogued as rs774944187, COSV99306077; called by muse, mutect2, varscan2
- ASMT | c.847G>A p.E283K (on ENST00000381229; = p.E311K on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101172362; called by muse, mutect2, varscan2
- ASTN1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 193/470 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866639170, COSV56061286; called by muse, mutect2, varscan2
- ASTN1 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1558045958, COSV56083968; called by muse, mutect2, varscan2
- ASTN2 | c.1777C>T p.L593F (on ENST00000313400 / NM_001365069.1; = p.L542F on NM_014010.5) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV100523716; called by muse, mutect2, varscan2
- ASTN2 | c.1711G>A p.D571N (on ENST00000313400 / NM_001365069.1; = p.D520N on NM_014010.5) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1212209181, COSV57796774; called by muse, mutect2, varscan2
- ASXL2 | c.883C>T p.L295F | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV99709965; called by muse, mutect2, varscan2
- ATG2B | c.5792C>T p.S1931F | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55890522, COSV99951896; called by muse, mutect2, varscan2
- ATIC | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs779389808, COSV99377313; called by muse, mutect2, varscan2
- ATP11A | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 31/107 reads (29%) | catalogued as rs755950468, COSV99367169; called by muse, mutect2, varscan2
- ATP11A | c.3111del p.S1038Rfs*15 | Frame Shift Del (DEL) | VAF 18/93 reads (19%) | catalogued as rs760821785; called by mutect2, pindel, varscan2
- ATP1A3 | c.1102G>A p.E368K (on ENST00000545399 / NM_001256214.2; = p.E355K on NM_152296.5) | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100131812; called by muse, mutect2, varscan2
- ATP9A | c.2783T>C p.V928A | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as COSV100124173; called by muse, mutect2, varscan2
- ATRIP | c.2227G>A p.E743K (on ENST00000320211 / NM_130384.3; = p.E716K on NM_032166.4) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV56496996, COSV99603804; called by muse, mutect2, varscan2
- AUH | c.660del p.T221Hfs*33 | Frame Shift Del (DEL) | VAF 31/95 reads (33%) | catalogued as rs781142774; called by mutect2, pindel, varscan2
- AZIN1 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 104/169 reads (62%) | catalogued as COSV100457288; called by muse, mutect2, varscan2
- B3GLCT | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 68/298 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.772); catalogued as rs989562225, COSV100587035; called by muse, varscan2
- B3GLCT | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 70/298 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100587036, COSV58456897; called by muse, varscan2
- B3GNT8 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as rs762599385, COSV99524372; called by muse, mutect2, varscan2
- B3GNTL1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1052712690, COSV100301631; called by muse, mutect2, varscan2
- B4GALT2 | c.487C>T p.H163Y | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV99356208; called by muse, mutect2, varscan2
- BBS2 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99801986; called by muse, mutect2, varscan2
- BCL6 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV99215279; called by muse, mutect2, varscan2
- BEND5 | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV100884075; called by muse, mutect2, varscan2
- BEST2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as rs1407840110, COSV99244147; called by muse, mutect2, varscan2
- BEX2 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 56/68 reads (82%) | SIFT deleterious (0.05); PolyPhen benign (0.301); catalogued as COSV101012764; called by muse, mutect2, varscan2
- BHMT | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99165360; called by muse, mutect2, varscan2
- BLK | c.121C>T p.L41= | Splice Region (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99376764; called by muse, mutect2, varscan2
- BLK | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as rs761710037, COSV52054682; called by muse, mutect2, varscan2
- BPI | c.380G>A p.R127K (on ENST00000262865; = p.R123K on NM_001725.3) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV104394560, COSV99480313; called by muse, mutect2, varscan2
- BRINP1 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs987725274, COSV56293277; called by muse, mutect2, varscan2
- BRWD1 | c.496A>G p.T166A | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.112); catalogued as COSV100312622; called by muse, mutect2, varscan2
- BSN | c.2165C>T p.S722F | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV56517477; called by muse, varscan2
- BTBD11 | c.2743C>T p.H915Y (on ENST00000280758 / NM_001018072.2; = p.H452Y on NM_001017523.2) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV99774723; called by muse, mutect2
- C10orf90 | c.1049T>G p.L350W | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as COSV99502863; called by muse, mutect2, varscan2
- C12orf29 | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.577); catalogued as COSV100795002; called by muse, mutect2, varscan2
- C12orf40 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV61129266; called by muse, mutect2, varscan2
- C1QTNF8 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100116298; called by muse, varscan2
- C3orf14 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51707184; called by muse, mutect2, varscan2
- C7 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.37); PolyPhen probably damaging (1); catalogued as rs1176163705, COSV100495243; called by muse, varscan2
- C9orf64 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.967); catalogued as COSV59032307; called by muse, mutect2, varscan2
- C9orf78 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV59610856; called by muse, mutect2, varscan2
- CACNA1B | c.6515C>T p.P2172L | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV99494579; called by muse, mutect2
- CACNA1G | c.3512C>T p.S1171F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs759759601, COSV100661005; ClinVar: uncertain significance; called by muse, varscan2
- CACTIN | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1226199053, COSV99698171; called by muse, mutect2
- CAMK4 | c.549C>T p.I183= | Splice Region (SNP) | VAF 25/67 reads (37%) | catalogued as rs267600313, COSV56662562; called by muse, mutect2, varscan2
- CAP2 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100011902; called by muse, mutect2, varscan2
- CARD11 | c.2839G>A p.E947K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as COSV100829063; called by muse, mutect2, varscan2
- CARD11 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV101210433, COSV67800265; called by muse, mutect2, varscan2
- CASKIN2 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1185415427, COSV100395205; called by muse, mutect2, varscan2
- CASR | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.234); catalogued as rs121909262, CM950198, COSV56133823; called by muse, mutect2, varscan2
- CATSPERB | c.2786C>T p.S929L | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV56429745; called by muse, mutect2, varscan2
- CATSPERB | c.1796G>A p.G599E | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.382); catalogued as COSV56437974; called by muse, mutect2, varscan2
- CATSPERG | c.3308G>A p.W1103* | Nonsense Mutation (SNP) | VAF 40/96 reads (42%) | catalogued as rs904604358, COSV53051344; called by muse, mutect2, varscan2
- CAVIN1 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.085); catalogued as COSV100824493, COSV63812761; called by muse, mutect2, varscan2
- CAVIN2 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs367846421; called by muse, mutect2, varscan2
- CBY2 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100137377; called by muse, mutect2, varscan2
- CCBE1 | c.213G>A p.R71= | Splice Region (SNP) | VAF 19/62 reads (31%) | catalogued as COSV101232766; called by muse, mutect2, varscan2
- CCDC12 | c.190C>T p.P64S (on ENST00000425441 / NM_001277074.1; = p.P77S on NM_144716.5) | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99438604; called by muse, mutect2
- CCDC136 | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99921953; called by muse, mutect2, varscan2
- CCDC146 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV53546929; called by muse, mutect2, varscan2
- CCDC170 | c.1057C>T p.R353* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as rs751935416, COSV99498037; called by muse, mutect2, varscan2
- CCDC178 | c.1583G>A p.R528K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100282893, COSV55770453; called by muse, mutect2, varscan2
- CCDC178 | c.1273-1G>A p.X425_splice | Splice Site (SNP) | VAF 17/46 reads (37%) | catalogued as COSV55778360; called by muse, varscan2
- CCDC178 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs976647667, COSV100282897; called by muse, mutect2, varscan2
- CCDC33 | c.717G>A p.M239I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as COSV58348493; called by muse, mutect2, varscan2
- CCDC33 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV100350314; called by muse, mutect2, varscan2
- CCDC88B | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV100104888; called by muse, mutect2
- CCKAR | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs200084604, COSV55160723; called by muse, mutect2, varscan2
- CCSER1 | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1421725979, COSV100387168; called by muse, mutect2, varscan2
- CD163 | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.134); catalogued as COSV63136122; called by muse, mutect2, varscan2
- CD1B | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV100939115; called by muse, mutect2, varscan2
- CD300A | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 64/110 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs754986019, COSV60409512; called by muse, mutect2, varscan2
- CD72 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 86/221 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868360829, COSV99427229; called by muse, mutect2, varscan2
- CDC7 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV99319493; called by muse, mutect2, varscan2
- CDC7 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs747527444, COSV99319494; called by muse, mutect2, varscan2
- CDH11 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV51758291; called by muse, mutect2, varscan2
- CDK12 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71000304; called by muse, mutect2, varscan2
- CDK18 | c.1481-1G>A p.X494_splice (on ENST00000506784 / NM_212503.3; = p.X464_splice on NM_002596.4) | Splice Site (SNP) | VAF 19/47 reads (40%) | catalogued as COSV100773896; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5056C>T p.P1686S | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1028422918, COSV62575029; called by muse, mutect2, varscan2
- CDSN | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as rs1357471241, COSV99456562; called by muse, mutect2, varscan2
- CEACAM6 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV52269157; called by muse, mutect2, varscan2
- CEL | c.808C>T p.P270S (on ENST00000673714; = p.P267S on NM_001807.6) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.33); catalogued as COSV100672173; called by muse, mutect2, varscan2
- CEP112 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.644); catalogued as COSV67144190; called by muse, mutect2, varscan2
- CEP162 | c.1178A>T p.N393I | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV100002272; called by muse, mutect2, varscan2
- CEP290 | c.5287A>T p.I1763F | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100467581; called by muse, mutect2, varscan2
- CEP85 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 77/198 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.602); catalogued as COSV99431582; called by muse, mutect2, varscan2
- CERKL | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV59204694; called by muse, mutect2, varscan2
- CFAP20DC | c.2224C>T p.P742S (on ENST00000482387 / NM_001351530.2; = p.P491S on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.205); catalogued as COSV99917871; called by muse, mutect2, varscan2
- CFAP221 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.028); catalogued as COSV99731784; called by muse, mutect2, varscan2
- CFAP47 | c.2813G>A p.G938E | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99934109; called by muse, mutect2, varscan2
- CFAP52 | c.407G>A p.S136N | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); catalogued as rs751576882, COSV100234654, COSV100234984; called by muse, mutect2, varscan2
- CFAP74 | c.1376G>A p.W459* | Nonsense Mutation (SNP) | VAF 32/60 reads (53%) | catalogued as COSV54572196; called by muse, mutect2, varscan2
- CFHR3 | c.254-1G>A p.X85_splice | Splice Site (SNP) | VAF 15/33 reads (45%) | catalogued as COSV100807367; called by muse, mutect2, varscan2
- CHAT | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs202059535; called by muse, mutect2, varscan2
- CHGB | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749207026, COSV100972869, COSV66761987; called by muse, mutect2, varscan2
- CHRM2 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV100280535; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 23/58 reads (40%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNA2 | c.1144C>T p.R382W | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs188098799, COSV53556623; called by muse, mutect2, varscan2
- CHST9 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52453379; called by muse, mutect2, varscan2
- CHSY3 | c.2339A>T p.Y780F | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100518259; called by muse, mutect2, varscan2
- CIITA | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV100161242; called by muse, mutect2, varscan2
- CLBA1 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101120942; called by muse, mutect2, varscan2
- CLCN1 | c.2575G>A p.G859S | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1243522982, COSV100577591; called by muse, mutect2, varscan2
- CLCN1 | c.2806C>T p.P936S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.1); catalogued as COSV58376481; called by muse, mutect2, varscan2
- CLEC18B | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.199); catalogued as rs1358813191; called by mutect2, varscan2
- CLSTN2 | c.985G>T p.G329C | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101515400; called by muse, mutect2, varscan2
- CLUH | c.3872G>A p.G1291E (on ENST00000435359; = p.G1330E on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs559628095, COSV101425597; called by muse, mutect2, varscan2
- CMTR2 | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100578938; called by muse, mutect2, varscan2
- CMYA5 | c.2432C>T p.S811F | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs769282508, COSV71406247; called by muse, mutect2, varscan2
- CNGB1 | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs574295098, COSV51901177; called by muse, mutect2, varscan2
- CNN2 | c.111G>A p.W37* | Nonsense Mutation (SNP) | VAF 41/106 reads (39%) | catalogued as COSV99567523; called by muse, mutect2, varscan2
- CNTLN | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV99262393; called by muse, mutect2, varscan2
- CNTNAP4 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.285); catalogued as COSV100268965; called by muse, mutect2, varscan2
- CNTNAP5 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as rs369591290, COSV70510307; called by muse, mutect2
- COL14A1 | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.75); catalogued as rs1443750011, COSV52874655; called by muse, mutect2, varscan2
- COL18A1 | c.2594C>T p.P865L (on ENST00000359759 / NM_130444.3; = p.P630L on NM_030582.4) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as rs1272945203, COSV62709067; called by muse, mutect2, varscan2
- COL19A1 | c.2925G>A p.M975I | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV59572421; called by muse, mutect2, varscan2
- COL20A1 | c.3656C>T p.P1219L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.702); catalogued as rs546339693, COSV100489772; called by muse, mutect2, varscan2
- COL20A1 | c.3818G>A p.G1273E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV100489777; called by muse, mutect2, varscan2
- COL21A1 | c.2659G>A p.G887R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99777027; called by muse, mutect2, varscan2
- COL2A1 | c.3937G>A p.V1313I | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV61529482; called by muse, mutect2, varscan2
- COL3A1 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV100482244; called by muse, mutect2, varscan2
- COL3A1 | c.2435C>T p.P812L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV100482247; called by muse, mutect2, varscan2
- COL4A1 | c.1867C>T p.P623S | Missense Mutation (SNP) | VAF 107/210 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as rs866989381, COSV65430867; called by muse, mutect2, varscan2
- COL4A5 | c.4873C>T p.R1625C | Missense Mutation (SNP) | VAF 59/69 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865842167, COSV60362202; called by muse, mutect2, varscan2
- COL5A1 | c.3766C>T p.P1256S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV65669008; called by muse, mutect2, varscan2
- COL6A3 | c.2718G>A p.M906I | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV99795874; called by muse, mutect2, varscan2
- COL6A6 | c.4900G>A p.E1634K | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs1044475492, COSV100649657; called by muse, mutect2, varscan2
- COL7A1 | c.8243C>T p.P2748L | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV56477041; called by muse, mutect2, varscan2
- COL7A1 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs778085630, COSV60390567; called by muse, mutect2, varscan2
- COL9A3 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.996); catalogued as COSV100673231; called by muse, mutect2, varscan2
- COPS5 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV100769855; called by muse, mutect2, varscan2
- CORIN | c.712C>T p.L238F | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV99902673; called by muse, mutect2, varscan2
- CPE | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV101291531; called by muse, mutect2, varscan2
- CPLX2 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as rs1212414716, COSV100852995; called by muse, mutect2, varscan2
- CPNE4 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1355312776, COSV101456545; called by muse, mutect2, varscan2
- CPQ | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.023); catalogued as rs772446810, COSV99610385; called by muse, mutect2, varscan2
- CR1 | c.5847G>A p.W1949* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as rs867358083, COSV100888015, COSV65463219; called by muse, mutect2, varscan2
- CR2 | c.2509G>A p.V837M | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.176); catalogued as COSV100889505; called by muse, mutect2, varscan2
- CRB1 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.433); catalogued as COSV100957607, COSV66332650; called by muse, mutect2, varscan2
- CRELD1 | c.1073T>C p.M358T | Missense Mutation (SNP) | VAF 102/221 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV99926236; called by muse, mutect2, varscan2
- CRISP2 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs200917120, COSV59254001, COSV59255565; called by muse, mutect2, varscan2
- CRYBB2 | c.54G>A p.K18= | Splice Region (SNP) | VAF 8/28 reads (29%) | catalogued as CS105907, COSV101236693; called by muse, mutect2
- CRYZ | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61716986; called by muse, mutect2, varscan2
- CSMD3 | c.9899G>A p.G3300E (on ENST00000297405 / NM_001363185.1; = p.G3131E on NM_052900.3) | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52103513; called by muse, mutect2, varscan2
- CSMD3 | c.4036T>C p.Y1346H (on ENST00000297405 / NM_001363185.1; = p.Y1242H on NM_052900.3) | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs763295155, COSV52251924; called by muse, mutect2, varscan2
- CSMD3 | c.1373G>T p.G458V (on ENST00000297405 / NM_001363185.1; = p.G354V on NM_052900.3) | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52142936, COSV52200982; called by muse, mutect2, varscan2
- CSMD3 | c.1372G>A p.G458R (on ENST00000297405 / NM_001363185.1; = p.G354R on NM_052900.3) | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52145607, COSV52179681; called by muse, mutect2, varscan2
- CTAGE1 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV66943522; called by muse, mutect2, varscan2
- CTRC | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as COSV101036260; called by muse, mutect2, varscan2
- CTSC | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as rs1044703733, CM993137, COSV99910421; called by muse, mutect2, varscan2
- CTTNBP2 | c.2842C>T p.R948W | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750549413, COSV50389478; called by muse, mutect2, varscan2
- CTU2 | c.865T>A p.W289R | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.536); catalogued as COSV99965139; called by muse, mutect2, varscan2
- CUBN | c.9561G>A p.W3187* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV100911905; called by muse, mutect2, varscan2
- CUBN | c.3724G>A p.D1242N | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as rs764813467, COSV100911906; called by muse, mutect2, varscan2
- CUTA | c.476C>T p.P159L (on ENST00000488034 / NM_001014840.2; = p.P136L on NM_015921.3) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.865); catalogued as rs752519101, COSV99537706; called by muse, mutect2, varscan2
- CUX2 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99918327; called by muse, mutect2, varscan2
- CUX2 | c.1225C>T p.L409F | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV55627371; called by muse, mutect2, varscan2
- CUX2 | c.3820G>A p.E1274K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as COSV55632376; called by muse, mutect2, varscan2
- CWF19L2 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.15); catalogued as COSV99978034; called by muse, mutect2, varscan2
- CXCL9 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.093); catalogued as COSV53578381, COSV99345623; called by muse, mutect2, varscan2
- CYLD | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1449388332, COSV100282077; called by muse, mutect2, varscan2
- CYP2C18 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV99608144; called by muse, mutect2, varscan2
- CYP2C19 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.505); catalogued as COSV100990196; called by muse, mutect2, varscan2
- CYP46A1 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs1300487337, COSV55897198; called by muse, mutect2, varscan2
- CYP4A11 | c.1089G>A p.W363* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100152078; called by muse, mutect2
- CYP4F12 | c.1486A>G p.T496A | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV100215542; called by muse, mutect2, varscan2
- CYP4F2 | c.602A>G p.D201G | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771516911, COSV99171033; called by muse, mutect2, varscan2
- CYSLTR1 | c.71A>G p.Q24R | Missense Mutation (SNP) | VAF 62/76 reads (82%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100964701; called by muse, mutect2, varscan2
- DAAM1 | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.953); catalogued as rs767797655, COSV62834416; called by muse, mutect2, varscan2
- DAAM2 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99224240; called by muse, mutect2, varscan2
- DAB2 | c.2167T>C p.S723P | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV100297743; called by muse, mutect2, varscan2
- DAGLA | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs887239641, COSV99943861; called by muse, mutect2, varscan2
- DCDC1 | c.3585G>A p.M1195I (on ENST00000597505 / NM_001367979.1; = p.M302I on NM_020869.3) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV60304314; called by muse, mutect2, varscan2
- DCLK1 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as COSV55171740; called by muse, mutect2, varscan2
- DCXR | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 31/72 reads (43%) | catalogued as rs781551153, COSV100178777, COSV100178923; called by muse, mutect2, varscan2
- DDR1 | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.067); catalogued as COSV100240853; called by muse, mutect2, varscan2
- DDX4 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100737255; called by muse, mutect2, varscan2
- DDX52 | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as rs768040442; called by muse, mutect2, varscan2
- DEFB115 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV68723249, COSV68723332, COSV68723346; called by muse, mutect2, varscan2
- DENND2A | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV99325405; called by muse, mutect2, varscan2
- DEUP1 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV99976526; called by muse, mutect2, varscan2
- DGCR8 | c.1627G>A p.G543S | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT tolerated (0.62); PolyPhen probably damaging (1); catalogued as COSV100707752; called by muse, mutect2, varscan2
- DGCR8 | c.1628G>A p.G543D | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100707753; called by muse, mutect2, varscan2
- DGKB | c.1282C>G p.L428V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as COSV99335586; called by muse, varscan2
- DGKQ | c.2096C>T p.S699F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs772812460, COSV53280759; called by mutect2, varscan2
- DIS3 | c.1912C>T p.R638* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as rs770832001, COSV66705727; called by muse, mutect2, varscan2
- DKK2 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs770400633, COSV53394433; called by muse, mutect2, varscan2
- DLG5 | c.3521C>T p.S1174F | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV100967185; called by muse, mutect2, varscan2
- DLGAP1 | c.2245C>T p.H749Y | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV100227394; called by muse, mutect2, varscan2
- DLL4 | c.636G>A p.W212* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99989536; called by muse, mutect2, varscan2
- DMAC2 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV55727145; called by muse, mutect2
- DMGDH | c.222A>T p.K74N | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs1175254929, COSV99668309; called by muse, mutect2, varscan2
- DMKN | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1281229656, COSV100303051; called by muse, mutect2, varscan2
- DMKN | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV100303057; called by muse, mutect2, varscan2
- DMRTB1 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1441135099, COSV101008220; called by muse, mutect2, varscan2
- DNAH1 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV70227981; called by muse, mutect2, varscan2
- DNAH10 | c.8366C>T p.P2789L (on ENST00000409039; = p.P2728L on NM_207437.3) | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101291876; called by muse, mutect2, varscan2
- DNAH11 | c.5665G>A p.G1889R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100176253; called by muse, mutect2, varscan2
- DNAH11 | c.11870G>A p.G3957E | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV100176256, COSV60939287; called by muse, mutect2, varscan2
- DNAH5 | c.12631G>A p.E4211K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762673561, COSV54204698, COSV54216995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.9609G>A p.M3203I | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.17); catalogued as COSV54234269; called by muse, mutect2, varscan2
- DNAH7 | c.7561G>A p.E2521K | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV100413439; called by muse, mutect2, varscan2
- DNAJC21 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.355); catalogued as rs1561183481, COSV57762022; called by muse, mutect2, varscan2
- DNASE1 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.62); catalogued as COSV99892257; called by muse, mutect2, varscan2
- DNER | c.1706G>C p.C569S | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100518074; called by muse, mutect2, varscan2
- DNMT1 | c.2334G>A p.R778= | Splice Region (SNP) | VAF 56/116 reads (48%) | catalogued as COSV100531577; called by muse, mutect2, varscan2
- DOCK2 | c.3719C>T p.A1240V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99909644; called by muse, mutect2, varscan2
- DOCK3 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV99808471; called by muse, varscan2
- DOCK3 | c.3563C>T p.S1188F | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs868683773, COSV56501731; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DPP4 | c.595A>G p.T199A | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100858642; called by muse, mutect2, varscan2
- DRAM1 | c.200-1G>A p.X67_splice | Splice Site (SNP) | VAF 19/53 reads (36%) | catalogued as COSV99315371, COSV99315755; called by muse, mutect2, varscan2
- DSC3 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV64571450; called by muse, mutect2, varscan2
- DSCAM | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs1183479997, COSV68021948; called by muse, mutect2, varscan2
- DUOX2 | c.944-1G>A p.X315_splice | Splice Site (SNP) | VAF 12/37 reads (32%) | catalogued as rs1239852850, COSV100545687; called by muse, mutect2, varscan2
- DVL2 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.621); catalogued as COSV99138262; called by muse, mutect2, varscan2
- DYSF | c.2764G>A p.A922T | Missense Mutation (SNP) | VAF 194/482 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV50522547; called by muse, mutect2, varscan2
- E2F3 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 22/73 reads (30%) | catalogued as COSV100685650; called by muse, mutect2, varscan2
- ECT2L | c.1636G>A p.D546N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs779772772, COSV100871725; called by muse, mutect2, varscan2
- EEA1 | c.3542C>T p.S1181F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV100466892; called by mutect2, varscan2
- EEF1AKNMT | c.951G>A p.M317I (on ENST00000361735 / NM_015935.5; = p.M231I on NM_014955.3) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV100675732; called by muse, mutect2, varscan2
- EEF2 | c.731T>C p.L244S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV100500523; called by muse, mutect2, varscan2
- EFEMP2 | c.1217C>T p.T406M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs372299119; called by muse, mutect2, varscan2
- EGLN3 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99164279; called by muse, mutect2, varscan2
- ELOA2 | c.2038G>A p.G680R | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV99795723; called by muse, mutect2, varscan2
- ELOA2 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.868); catalogued as COSV55299125; called by muse, mutect2, varscan2
- ELOVL4 | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as COSV100876130, COSV100876381; called by muse, mutect2, varscan2
- ELSPBP1 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as rs148276275; called by muse, mutect2
- EMSY | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58266965; called by muse, mutect2, varscan2
- ENAM | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs149086531; called by muse, mutect2, varscan2
- ENPP1 | c.1258C>T p.L420F | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.464); catalogued as COSV100719317; called by muse, mutect2, varscan2
- ENTPD2 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100445568; called by muse, varscan2
- EP300 | c.7097G>A p.S2366N | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV99607053; called by muse, mutect2
- EPHA10 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60405183; called by muse, mutect2, varscan2
- EPM2AIP1 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.391); catalogued as COSV99212297; called by muse, mutect2, varscan2
- EPPIN | c.93G>A p.R31= | Splice Region (SNP) | VAF 42/101 reads (42%) | catalogued as COSV100323062; called by muse, mutect2, varscan2
- EPS15L1 | c.2150C>T p.S717F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV50167279; called by muse, mutect2, varscan2
- ERG | c.1174C>T p.R392C (on ENST00000398919 / NM_001243428.1; = p.R368C on NM_004449.4) | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776452839, COSV55730767; called by muse, mutect2, varscan2
- ERICH3 | c.4240G>A p.E1414K | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.057); catalogued as rs907093983, COSV100443119; called by muse, mutect2, varscan2
- ERICH3 | c.2186C>T p.S729L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as COSV58599934; called by muse, varscan2
- ESCO1 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99331753; called by muse, mutect2, varscan2
- ESRRG | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs267598381, COSV63152230; called by muse, mutect2, varscan2
- EVI5L | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.146); catalogued as COSV54489602; called by mutect2, varscan2
- EXD1 | c.568T>C p.S190P | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100153454; called by muse, mutect2, varscan2
- EXOC6B | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs199672443; called by muse, mutect2, varscan2
- EXOSC10 | c.2450C>T p.P817L (on ENST00000376936 / NM_001001998.3; = p.P792L on NM_002685.4) | Missense Mutation (SNP) | VAF 165/465 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100442046; called by muse, mutect2, varscan2
- EXOSC10 | c.2449C>T p.P817S (on ENST00000376936 / NM_001001998.3; = p.P792S on NM_002685.4) | Missense Mutation (SNP) | VAF 166/470 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV58665590; called by muse, mutect2, varscan2
- FAAH2 | c.767T>G p.F256C | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100887101; called by muse, mutect2, varscan2
- FABP6 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs772708229, COSV67436802; called by mutect2, varscan2
- FAHD2B | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99737847; called by muse, mutect2, varscan2
- FAM110B | c.879G>A p.M293I | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100825956; called by muse, mutect2, varscan2
- FAM135B | c.1948G>T p.E650* | Nonsense Mutation (SNP) | VAF 30/98 reads (31%) | catalogued as COSV52703694, COSV99417489; called by muse, mutect2, varscan2
- FAM155A | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs921482748, COSV65578670; called by muse, mutect2, varscan2
- FAM181A | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV99967736; called by muse, mutect2, varscan2
- FAM200A | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV101282694; called by muse, mutect2, varscan2
- FAM219A | c.280A>G p.K94E (on ENST00000445726; = p.K77E on NM_147202.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV99896612; called by muse, mutect2, varscan2
- FAM234B | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV99545277; called by muse, mutect2, varscan2
- FAM83B | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100173907, COSV60927298; called by muse, mutect2, varscan2
- FAM83B | c.2959C>T p.R987C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs768677387, COSV60923191; called by muse, mutect2, varscan2
- FAT1 | c.10190T>C p.L3397P | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as rs763175952, COSV101498607; called by muse, mutect2, varscan2
- FAT3 | c.4123G>A p.D1375N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99960304; called by muse, mutect2, varscan2
- FAT3 | c.7990G>A p.G2664S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.054); catalogued as rs983277945, COSV99960309; called by muse, mutect2, varscan2
- FAT4 | c.5822C>T p.P1941L | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs771880094, COSV100626950; called by muse, mutect2, varscan2
- FBLIM1 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs923782709, COSV60029047; called by muse, mutect2, varscan2
- FBN1 | c.2210G>A p.G737E | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as CM104794, COSV100353833; called by muse, mutect2, varscan2
- FBN3 | c.8063G>A p.R2688Q | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs375603937; called by muse, mutect2, varscan2
- FBN3 | c.3952G>A p.E1318K | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757402144; called by muse, mutect2
- FBXO39 | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100386092; called by muse, mutect2, varscan2
- FCER1A | c.54C>T p.F18= | Splice Region (SNP) | VAF 50/150 reads (33%) | catalogued as rs1268348044, COSV63666446; called by muse, mutect2, varscan2
- FGL2 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV50381470; called by muse, mutect2, varscan2
- FHIT | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV59319257; called by muse, mutect2, varscan2
- FLG | c.2785G>A p.G929S | Missense Mutation (SNP) | VAF 164/412 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.606); catalogued as rs1262998609, COSV100910332; called by muse, varscan2
- FMO4 | c.1498C>T p.R500* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as rs145740321; called by muse, mutect2, varscan2
- FOXA2 | c.242C>T p.S81F (on ENST00000377115 / NM_153675.3; = p.S87F on NM_021784.5) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV101008208; called by muse, mutect2, varscan2
- FOXG1 | c.1201T>A p.S401T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.484); catalogued as COSV100486481; called by muse, mutect2, varscan2
- FOXK1 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100194477; called by muse, mutect2, varscan2
- FOXO1 | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as rs199932286, COSV65426257; called by muse, mutect2, varscan2
- FOXP4 | c.1319G>A p.R440Q (on ENST00000307972 / NM_001012426.1; = p.R427Q on NM_138457.3) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs576059149, COSV57220668; called by mutect2, varscan2
- FPR1 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.029); catalogued as COSV59050940; called by muse, mutect2, varscan2
- FREM1 | c.3494A>T p.E1165V | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV101083584; called by muse, mutect2, varscan2
- FRRS1 | c.1333T>C p.Y445H | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.694); catalogued as COSV99789586; called by muse, mutect2, varscan2
- FSD2 | c.964A>T p.K322* | Nonsense Mutation (SNP) | VAF 51/118 reads (43%) | catalogued as COSV100574979; called by muse, mutect2, varscan2
- FSHB | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.646); catalogued as rs267602841, COSV99569277; called by muse, mutect2, varscan2
- FSHR | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as rs775484603, COSV100436354; called by muse, mutect2, varscan2
- FUT9 | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.933); catalogued as COSV100132850; called by muse, mutect2, varscan2
- FYB1 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV60947098; called by muse, mutect2, varscan2
- G6PC | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 79/205 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750470654, CM980783, COSV53830216, COSV53831745; called by muse, mutect2, varscan2
- GABRB3 | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 48/96 reads (50%) | catalogued as COSV100157707, COSV100160635; called by muse, mutect2, varscan2
- GABRG1 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54954480, COSV54960971, COSV99777223; called by muse, mutect2, varscan2
- GABRR2 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV101298802; called by muse, mutect2, varscan2
- GALNT6 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100695259; called by muse, mutect2, varscan2
- GALNTL6 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.06); catalogued as COSV101560008; called by muse, mutect2, varscan2
- GAPVD1 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV99782486; called by muse, mutect2, varscan2
- GCM2 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs1430276294, COSV65276594; called by muse, mutect2, varscan2
- GCN1 | c.6946G>A p.D2316N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100324507, COSV56110265; called by muse, mutect2, varscan2
- GDAP1L1 | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 102/275 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV61158609; called by muse, mutect2, varscan2
- GET4 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs1365910783, COSV99768337; called by muse, mutect2, varscan2
- GGCX | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV99289573; called by muse, mutect2, varscan2
- GIMAP8 | c.1309+1G>A p.X437_splice | Splice Site (SNP) | VAF 20/44 reads (45%) | catalogued as COSV56230290; called by muse, mutect2
- GJA10 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV65355239; called by muse, mutect2, varscan2
- GJB3 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs961534236, COSV64904833; called by muse, mutect2, varscan2
- GK2 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150499437, COSV62627775; called by muse, mutect2, varscan2
- GLI2 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374155310, CM107450; called by muse, mutect2, varscan2
- GLI2 | c.1343G>A p.G448E (on ENST00000361492 / NM_001374353.1; = p.G465E on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100082093; called by muse, mutect2, varscan2
- GLI4 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 144/240 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as rs761788760, COSV100390819, COSV100391199; called by muse, varscan2
- GLUL | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.884); catalogued as COSV100091715; called by muse, mutect2, varscan2
- GLYATL2 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54849906, COSV99780152; called by muse, mutect2, varscan2
- GMNN | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV100017634; called by muse, mutect2, varscan2
- GNAZ | c.640C>A p.H214N | Missense Mutation (SNP) | VAF 89/224 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV99320334; called by muse, mutect2, varscan2
- GOT1L1 | c.522G>A p.Q174= | Splice Region (SNP) | VAF 22/76 reads (29%) | catalogued as COSV100294274; called by muse, mutect2, varscan2
- GPC5 | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.838); catalogued as COSV100992407, COSV100994956; called by muse, mutect2, varscan2
- GPR158 | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100892633; called by muse, mutect2, varscan2
- GPR158 | c.2812G>A p.D938N | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV100892635; called by muse, mutect2, varscan2
- GRHL2 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99305884; called by muse, mutect2, varscan2
- GRID2 | c.1559G>A p.G520E | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56174162, COSV99942302; called by muse, mutect2, varscan2
- GRIK2 | c.1104G>A p.W368* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100022024; called by muse, mutect2, varscan2
- GRIN2A | c.3977G>A p.G1326D | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1036750557, COSV100407642, COSV58031107; called by muse, mutect2, varscan2
- GRIP1 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99667603; called by muse, mutect2, varscan2
- GRIP1 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1209782109, COSV99667605; called by muse, mutect2, varscan2
- GRIP2 | c.2390G>A p.G797E (on ENST00000619221; = p.G700E on NM_001080423.4) | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99816844; called by muse, mutect2, varscan2
- GRM6 | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.348); catalogued as COSV51435546; called by muse, mutect2, varscan2
- GRXCR1 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV101295592; called by muse, mutect2, varscan2
- GRXCR2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.295); catalogued as rs867529802, COSV65061631; called by muse, mutect2, varscan2
- GSDMC | c.1195C>T p.L399F | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99415410; called by muse, mutect2, varscan2
- GSTA5 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757242778, COSV99489346; called by muse, mutect2, varscan2
- GTF3C1 | c.2893G>A p.V965M | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100648866; called by muse, mutect2, varscan2
- GTF3C1 | c.2299del p.S767Vfs*7 | Frame Shift Del (DEL) | VAF 31/86 reads (36%) | catalogued as rs1231771183; called by mutect2, pindel, varscan2
- GUCY2C | c.2584C>T p.H862Y | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV99663118; called by muse, mutect2, varscan2
- GUCY2D | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); catalogued as COSV99643653; called by muse, mutect2, varscan2
- GULP1 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV100770037; called by muse, mutect2, varscan2
- GYS2 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99679328; called by muse, mutect2, varscan2
- H1-4 | c.190A>G p.K64E | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99175189; called by muse, mutect2, varscan2
- HACE1 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as COSV99493183; called by muse, mutect2, varscan2
- HBP1 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99752914; called by muse, mutect2, varscan2
- HCFC1 | c.1985C>T p.T662I | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100128261; called by muse, mutect2, varscan2
- HDAC4 | c.2703dup p.M902Hfs*5 | Frame Shift Ins (INS) | VAF 8/12 reads (67%) | catalogued as rs747537946; called by mutect2, varscan2
- HEATR4 | c.2227A>C p.T743P | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV100620118; called by muse, mutect2, varscan2
- HEATR5B | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99247972; called by muse, mutect2, varscan2
- HECW1 | c.2774C>T p.S925F | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs778042441, COSV101222536; called by muse, mutect2, varscan2
- HEPHL1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV59892172; called by muse, mutect2, varscan2
- HIRA | c.2866C>T p.R956* | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | catalogued as COSV54274039; called by muse, mutect2, varscan2
- HLA-B | c.681C>A p.C227* | Nonsense Mutation (SNP) | VAF 49/139 reads (35%) | catalogued as COSV69520836; called by muse, mutect2
- HLA-DMA | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs112631644, COSV100877642; called by muse, mutect2, varscan2
- HNF1A | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as CM082834, COSV57464432; called by muse, mutect2, varscan2
- HNF4A | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs193922480, CM121659, COSV100290943; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNF4G | c.625G>A p.E209K (on ENST00000354370 / NM_001330561.2; = p.E256K on NM_004133.5) | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.911); catalogued as COSV100583904; called by muse, varscan2
- HNF4G | c.676C>T p.P226S (on ENST00000354370 / NM_001330561.2; = p.P273S on NM_004133.5) | Missense Mutation (SNP) | VAF 89/326 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100583906; called by muse, varscan2
- HOXD13 | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101184090; called by muse, mutect2, varscan2
- HOXD9 | c.68A>G p.D23G | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50891144; called by muse, mutect2, varscan2
- HPS4 | c.1205G>C p.C402S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100403881; called by muse, mutect2, varscan2
- HSD17B2 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1313929620, COSV99556302; called by muse, mutect2, varscan2
- HSD17B3 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs779332674, COSV100931230; called by muse, mutect2, varscan2
- HSPA1L | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65148705; called by muse, mutect2, varscan2
- HSPG2 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1344334039, COSV101012832; called by muse, mutect2, varscan2
- HTR1F | c.698G>A p.S233N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.239); catalogued as rs759114776, COSV100137884; called by muse, mutect2, varscan2
- HTT | c.7735C>T p.P2579S | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100750271; called by muse, mutect2, varscan2
- HYDIN | c.13609G>A p.G4537R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101124790; called by muse, mutect2, varscan2
- IFITM3 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV101296758; called by muse, mutect2, varscan2
- IFNA14 | c.101A>G p.N34S | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.045); catalogued as COSV101207282; called by muse, mutect2, varscan2
- IFRD1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.099); catalogued as COSV99133530; called by muse, mutect2, varscan2
- IFTAP | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs181985480, COSV57557751; called by muse, mutect2, varscan2
- IGDCC3 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.11); catalogued as COSV100030535; called by muse, mutect2
- IGF1 | c.219C>T p.F73= | Splice Region (SNP) | VAF 16/53 reads (30%) | catalogued as COSV100190342; called by muse, mutect2, varscan2
- IGFL4 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as COSV100890811, COSV66618739; called by muse, mutect2, varscan2
- IGHA1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs1286596126; called by muse, mutect2, varscan2
- IGHG4 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 90/236 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs756452414; called by muse, mutect2, varscan2
- IGHV3-66 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 79/246 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.928); catalogued as rs1555573015; called by muse, mutect2, varscan2
- IGHV7-81 | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs377365803; called by muse, mutect2, varscan2
- IGSF21 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.368); catalogued as rs772931608, COSV99243382; called by muse, mutect2, varscan2
- IGSF8 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs147326210; called by muse, mutect2, varscan2
- IL12RB1 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs773520745, CM066883, COSV100442715; called by muse, mutect2
- IL3 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.076); catalogued as rs773788934, COSV57309036; called by muse, mutect2, varscan2
- ILDR1 | c.1301C>T p.P434L (on ENST00000344209 / NM_001199799.2; = p.P390L on NM_175924.4) | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs760257421, COSV56548831; called by muse, mutect2, varscan2
- INF2 | c.3304C>T p.P1102S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs1309680057, COSV99383393; called by muse, mutect2, varscan2
- INPP1 | c.663G>A p.W221* | Nonsense Mutation (SNP) | VAF 72/186 reads (39%) | catalogued as COSV100487060, COSV59416227; called by muse, mutect2, varscan2
- INSL6 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV101068425; called by muse, mutect2, varscan2
- IQGAP2 | c.2105A>T p.K702I | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV99166632; called by muse, mutect2, varscan2
- IQGAP3 | c.3142G>A p.G1048R | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100752018; called by muse, mutect2, varscan2
- IRAG1 | c.1185G>A p.W395* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV101350852; called by muse, mutect2, varscan2
- IREB2 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV99358966; called by muse, mutect2, varscan2
- IRF2BP1 | c.1622C>T p.A541V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.258); catalogued as COSV100138777; called by muse, mutect2, varscan2
- IRGC | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.223); catalogued as rs774637358, COSV99745954; called by muse, mutect2, varscan2
- ISG20L2 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100493900; called by muse, mutect2, varscan2
- ISL1 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV100044934; called by muse, mutect2
- ITGA4 | c.1836G>A p.M612I | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267599106, COSV51998079, COSV52000901; called by muse, mutect2, varscan2
- ITGA4 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.721); catalogued as COSV101223025, COSV67898485; called by muse, mutect2, varscan2
- ITGAE | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV53990712, COSV99560144; called by muse, mutect2, varscan2
- ITGB6 | c.1529C>T p.S510F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.151); catalogued as COSV99324026; called by muse, mutect2, varscan2
- ITGB8 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.043); catalogued as COSV99750354; called by muse, mutect2, varscan2
- ITIH1 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV56256625; called by muse, mutect2, varscan2
- ITIH6 | c.3308G>A p.G1103E | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV99512724; called by muse, mutect2, varscan2
- ITPR1 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57012216; called by muse, mutect2, varscan2
- IVL | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.146); catalogued as rs376485946; called by muse, mutect2, varscan2
- JAML | c.550C>T p.R184C (on ENST00000356289 / NM_001098526.2; = p.R174C on NM_153206.3) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs774147626, COSV52627117, COSV52627225; called by muse, mutect2, varscan2
- JCAD | c.3058C>T p.R1020W | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as rs1564442039, COSV64760636; called by muse, mutect2, varscan2
- JCAD | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.086); catalogued as rs752441025, COSV100947991, COSV100948577; called by muse, mutect2, varscan2
- JPH3 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as rs142136496; called by muse, mutect2, varscan2
- KALRN | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763633331, COSV53755131, COSV53780852; called by muse, mutect2, varscan2
- KANK4 | c.2383C>T p.P795S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as rs866759938, COSV100443061; called by muse, mutect2, varscan2
- KBTBD11 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV57223238; called by muse, mutect2
- KBTBD3 | c.930T>A p.Y310* | Nonsense Mutation (SNP) | VAF 28/84 reads (33%) | catalogued as COSV101595654; called by muse, mutect2, varscan2
- KCNA1 | c.767T>G p.F256C | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV101230085; called by muse, mutect2, varscan2
- KCNB2 | c.1356G>A p.M452I | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as COSV101578623; called by muse, mutect2, varscan2
- KCNB2 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.627); catalogued as rs1163367178, COSV73050155; called by muse, varscan2
- KCNC3 | c.2092C>T p.R698C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs780943930, COSV100979142; called by muse, mutect2, varscan2
- KCND2 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1310731566, COSV58576394; called by muse, mutect2, varscan2
- KCNH5 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as COSV59762878; called by muse, mutect2, varscan2
- KCNH7 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs776350714, COSV59783186; called by muse, mutect2, varscan2
- KCNK5 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs1047251906, COSV100851701; called by muse, mutect2, varscan2
- KCNQ2 | c.2360C>T p.S787F (on ENST00000359125 / NM_172107.4; = p.S759F on NM_004518.6) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100609265; called by muse, mutect2, varscan2
- KCNV2 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101172459, COSV66056035; called by muse, mutect2, varscan2
- KCTD20 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV54805144, COSV99535708; called by muse, mutect2, varscan2
- KDM3A | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs141469380, COSV100459905, COSV57217769; called by muse, mutect2, varscan2
- KDM4C | c.1092G>T p.R364S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV101184617; called by muse, mutect2, varscan2
- KDM6B | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.992); catalogued as COSV99640584; called by muse, mutect2, varscan2
- KEL | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100786813, COSV62337029; called by muse, mutect2, varscan2
- KEL | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); catalogued as rs1190597568, COSV100786814; called by muse, mutect2, varscan2
- KIAA0319 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100985114; called by muse, mutect2, varscan2
- KIAA1109 | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as COSV52662434; called by muse, mutect2, varscan2
- KIAA1210 | c.4108C>T p.P1370S | Missense Mutation (SNP) | VAF 93/123 reads (76%) | SIFT tolerated (0.55); PolyPhen benign (0.058); catalogued as COSV101273871; called by muse, mutect2, varscan2
- KIAA1549L | c.133C>T p.P45S (on ENST00000321505; = p.P342S on NM_012194.3) | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV99682499; called by muse, mutect2, varscan2
- KIAA1586 | c.1619C>T p.S540L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as rs1438334305, COSV100875266; called by muse, mutect2, varscan2
- KIAA1755 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV99641331; called by muse, mutect2, varscan2
- KIAA1755 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99641337; called by muse, mutect2, varscan2
- KIDINS220 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 72/184 reads (39%) | catalogued as COSV99874738; called by muse, mutect2, varscan2
- KIF16B | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100733620; called by muse, mutect2, varscan2
- KIF2B | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.131); catalogued as COSV99274473; called by muse, mutect2, varscan2
- KIF2B | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs199554010, COSV52131659, COSV99274477; called by muse, mutect2, varscan2
- KIF4A | c.3553C>T p.P1185S | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV100978522; called by muse, mutect2, varscan2
- KIF4A | c.3554C>T p.P1185L | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs866463544, COSV100978523, COSV100978578; called by muse, mutect2, varscan2
- KLB | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.281); catalogued as rs369333502, COSV57303863; called by muse, mutect2, varscan2
- KLC3 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV101228985; called by muse, mutect2, varscan2
- KLHL1 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100916855; called by muse, mutect2, varscan2
- KLHL13 | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 42/53 reads (79%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV53244388; called by muse, mutect2, varscan2
- KMT2D | c.2651C>T p.P884L | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as rs763105209, COSV99976686; called by muse, mutect2, varscan2
- KMT2E | c.2990C>T p.T997I | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV99995651; called by muse, mutect2, varscan2
- KNL1 | c.2189C>T p.S730L (on ENST00000346991 / NM_170589.5; = p.S704L on NM_144508.5) | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1476295069, COSV100705777; called by muse, mutect2, varscan2
- KRT34 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV101222519; called by muse, mutect2, varscan2
- KRT4 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99542529; called by muse, mutect2, varscan2
- KRT9 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.389); catalogued as rs759302830, COSV55853235, COSV55855613; called by muse, mutect2, varscan2
- KRTAP10-5 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 74/237 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV100551435, COSV100554113; called by muse, mutect2, varscan2
- KRTAP10-9 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100551436; called by muse, mutect2, varscan2
- LACRT | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57687688; called by muse, mutect2, varscan2
- LAMA2 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV70343566; called by muse, mutect2, varscan2
- LAMA5 | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.829); catalogued as rs138625956, COSV53369466; called by muse, mutect2
- LAMB3 | c.2483C>T p.A828V | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100620031; called by muse, mutect2, varscan2
- LAMC2 | c.3334C>G p.P1112A | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs780545822, COSV99916887; called by muse, mutect2, varscan2
- LCOR | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as COSV100603472; called by muse, mutect2, varscan2
- LDB2 | c.153G>A p.W51* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100452390; called by muse, mutect2, varscan2
- LGALS12 | c.284G>A p.W95* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as COSV99736768; called by muse, mutect2, varscan2
- LILRB1 | c.1322C>T p.P441L (on ENST00000427581; = p.P405L on NM_006669.6) | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV100206769; called by muse, varscan2
- LINGO2 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.17); catalogued as rs760441998, COSV58061005; called by muse, mutect2, varscan2
- LMAN2L | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747360404, COSV53841441; called by muse, mutect2, varscan2
- LNX2 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as rs756769196, COSV100310411; called by muse, mutect2, varscan2
- LPA | c.4460C>T p.P1487L | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as COSV100305860; called by muse, mutect2, varscan2
- LPIN3 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100952838, COSV100953057; called by muse, mutect2, varscan2
- LPO | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373986970; called by muse, mutect2, varscan2
- LRP1B | c.13784G>A p.R4595K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.197); catalogued as COSV101250309; called by muse, mutect2, varscan2
- LRP1B | c.12643G>A p.D4215N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.212); catalogued as rs147880892; called by muse, mutect2, varscan2
- LRP1B | c.11539G>A p.E3847K | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV101250311; called by muse, mutect2, varscan2
- LRP1B | c.8864C>T p.P2955L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV101250312; called by muse, mutect2, varscan2
- LRP1B | c.4306G>A p.E1436K | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV67284561; called by muse, mutect2, varscan2
- LRP1B | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as rs772923678, COSV67209160, COSV67248203; called by muse, mutect2, varscan2
- LRP2 | c.8005G>A p.G2669S | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99785975; called by muse, mutect2, varscan2
- LRP2 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55539624, COSV99785979; called by muse, mutect2, varscan2
- LRRCC1 | c.1691G>A p.R564K | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100835241; called by muse, mutect2, varscan2
- LRRK1 | c.3385G>T p.A1129S | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99437030; called by muse, mutect2, varscan2
- LRRK2 | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); catalogued as COSV100108760; called by muse, mutect2, varscan2
- LRRK2 | c.3892C>T p.P1298S | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs865865671, COSV54162911; called by muse, mutect2, varscan2
- LRRN1 | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100075958; called by muse, mutect2, varscan2
- LRRN1 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100075962; called by muse, mutect2, varscan2
- LSMEM1 | c.127+2T>C p.X43_splice | Splice Site (SNP) | VAF 27/85 reads (32%) | catalogued as COSV100456192; called by muse, mutect2, varscan2
- LTBP1 | c.3640C>T p.P1214S (on ENST00000404816 / NM_206943.4; = p.P888S on NM_000627.4) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.113); catalogued as COSV99697620; called by muse, mutect2, varscan2
- LYZL1 | c.239C>T p.A80V (on ENST00000375500; = p.A34V on NM_032517.6) | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.341); catalogued as COSV100973581; called by muse, mutect2, varscan2
- LZTS1 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); catalogued as rs1252505061, COSV99742547; called by muse, mutect2, varscan2
- MAB21L2 | c.201G>T p.E67D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV58261786, COSV58262206; called by muse, mutect2
- MAFK | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as rs1332156855, COSV52476053; called by muse, mutect2, varscan2
- MAGEA3 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 48/66 reads (73%) | SIFT tolerated (0.15); PolyPhen benign (0.19); catalogued as rs1556826582, COSV64755846; called by muse, mutect2, varscan2
- MAGEA6 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 112/138 reads (81%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); catalogued as COSV100262643; called by muse, mutect2, varscan2
- MAGEB2 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs368561784, COSV100975549; called by muse, mutect2, varscan2
- MAOA | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV100108511; called by muse, mutect2, varscan2
- MAOB | c.181G>C p.V61L | Missense Mutation (SNP) | VAF 47/66 reads (71%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as COSV100955863, COSV65205415; called by muse, mutect2, varscan2
- MAP2K3 | c.334G>A p.D112N (on ENST00000342679 / NM_145109.3; = p.D83N on NM_002756.4) | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs780836688, COSV100383248; called by muse, mutect2, varscan2
- MAP3K9 | c.2113C>T p.R705C (on ENST00000554752 / NM_001284230.1; = p.R719C on NM_033141.4) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs931525178, COSV67122919; called by muse, mutect2, varscan2
- MAP7 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs372940524, COSV63417239; called by muse, mutect2, varscan2
- MAPK8IP3 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1478564248, COSV99167612; called by muse, mutect2, varscan2
- MAPT | c.1900C>T p.R634C (on ENST00000262410 / NM_001377265.1; = p.R242C on NM_005910.5) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99289572; called by muse, mutect2
- MARCHF11 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as COSV100197222, COSV60137166; called by muse, mutect2, varscan2
- MAST3 | c.3221C>T p.S1074L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV99444095; called by muse, mutect2, varscan2
- MAST4 | c.5774C>A p.S1925Y (on ENST00000403625 / NM_001164664.2; = p.S1736Y on NM_015183.3) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV99842444; called by muse, mutect2, varscan2
- MCM2 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.831); catalogued as COSV99412663; called by muse, mutect2, varscan2
- MECOM | c.2738G>A p.G913E (on ENST00000468789 / NM_001105078.4; = p.G1101E on NM_004991.4) | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52964738; called by muse, varscan2
- MEI1 | c.2799G>A p.M933I | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV55901963; called by muse, mutect2, varscan2
- MFAP3 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100491463; called by muse, mutect2, varscan2
- MGAM | c.3569G>A p.S1190N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1380612816, COSV101527340; called by muse, mutect2
- MGAT5B | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100047078; called by muse, varscan2
- MIGA2 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99477325; called by muse, mutect2, varscan2
- MIOX | c.492C>A p.N164K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99326620; called by muse, mutect2, varscan2
- MIP | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57788917; called by muse, mutect2, varscan2
- MKX | c.547A>T p.N183Y | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV101008478; called by muse, mutect2, varscan2
- MLH1 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.212); catalogued as COSV99212298; called by muse, mutect2, varscan2
- MLXIP | c.2650A>T p.T884S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0.14); catalogued as COSV100038356; called by muse, mutect2, varscan2
- MMP13 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs760915237, COSV99506249; called by muse, mutect2, varscan2
- MN1 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.137); catalogued as COSV100179607; called by muse, mutect2, varscan2
- MORC1 | c.2761C>T p.R921C | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs748962195, COSV51725516, COSV99227366; called by muse, mutect2, varscan2
- MORC2 | c.296A>T p.Q99L (on ENST00000397641 / NM_001303256.3; = p.Q37L on NM_014941.3) | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53196184; called by muse, mutect2, varscan2
- MOXD1 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100381123; called by muse, mutect2, varscan2
- MRGPRF | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs1400513604, COSV100307751; called by muse, mutect2, varscan2
- MROH7 | c.2293G>A p.V765M | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV100272716; called by muse, mutect2, varscan2
- MSLN | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs781390078, COSV53502593; called by muse, mutect2, varscan2
- MTCL1 | c.3274C>T p.H1092Y (on ENST00000306329 / NM_001378206.1; = p.H773Y on NM_015210.4) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV100093126; called by muse, mutect2
- MTHFD1 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as rs920392170, COSV53702867; called by muse, mutect2, varscan2
- MTMR11 | c.1249C>T p.P417S (on ENST00000439741 / NM_001145862.2; = p.P345S on NM_181873.3) | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV54967205, COSV99640853; called by muse, mutect2, varscan2
- MTO1 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs767156523, COSV100940280; called by muse, mutect2, varscan2
- MTUS2 | c.3493C>T p.H1165Y (on ENST00000612955 / NM_001366650.1; = p.H144Y on NM_015233.6) | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs1429436905, COSV100040719; called by muse, mutect2, varscan2
- MUC16 | c.24781G>A p.E8261K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV101197482, COSV67473804; called by muse, mutect2, varscan2
- MUC16 | c.21074C>T p.S7025L | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV101197483; called by muse, mutect2, varscan2
- MUC16 | c.7778C>T p.P2593L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV67481828; called by muse, mutect2, varscan2
- MUC20 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.726); catalogued as rs3204353, COSV57848483; called by muse, mutect2
- MUC4 | c.596G>A p.W199* | Nonsense Mutation (SNP) | VAF 100/238 reads (42%) | catalogued as COSV100638717; called by muse, mutect2, varscan2
- MUC5B | c.11731G>A p.G3911R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV101499957; called by mutect2, varscan2
- MXRA5 | c.5024C>T p.P1675L | Missense Mutation (SNP) | VAF 103/126 reads (82%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs867173760, COSV99475419; called by muse, mutect2, varscan2
- MXRA5 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99475424, COSV99478551; called by muse, mutect2, varscan2
- MYBPC2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV100731517; called by muse, mutect2, varscan2
- MYBPC3 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99919746; called by muse, mutect2, varscan2
- MYCBP2 | c.12215T>C p.L4072P (on ENST00000357337; = p.L4110P on NM_015057.5) | Missense Mutation (SNP) | VAF 80/297 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100628927; called by muse, mutect2, varscan2
- MYEOV | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as rs763496982, COSV100456553; called by muse, mutect2, varscan2
- MYH13 | c.4144G>A p.D1382N | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs748820887, COSV99351792; called by muse, varscan2
- MYH13 | c.3442G>A p.E1148K | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs763795168, COSV52829170; called by muse, mutect2, varscan2
- MYH14 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs773685557, COSV99221448; called by muse, varscan2
- MYH3 | c.3085G>A p.E1029K | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV99877579; called by muse, mutect2, varscan2
- MYH4 | c.4640C>T p.S1547F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV55122946; called by muse, mutect2, varscan2
- MYH8 | c.4672G>A p.E1558K | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV101238073; called by muse, mutect2, varscan2
- MYH8 | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 117/309 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV101238074; called by muse, mutect2, varscan2
- MYH9 | c.1007A>G p.Q336R | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.176); catalogued as COSV99337632; called by muse, mutect2, varscan2
- MYL1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV61681269; called by mutect2, varscan2
- MYO18B | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100122317; called by muse, mutect2, varscan2
- MYO18B | c.7396G>A p.D2466N | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV100122318; called by muse, mutect2, varscan2
- MYO18B | c.7666G>A p.D2556N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs1240064865, COSV59148157; called by muse, mutect2, varscan2
- MYO7A | c.2926G>A p.E976K | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV68687098; called by muse, mutect2, varscan2
- MYO9A | c.4978C>T p.L1660F | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.043); catalogued as COSV100612462; called by muse, mutect2, varscan2
- MYOCD | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100589985; called by muse, mutect2, varscan2
- NAB2 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.619); catalogued as COSV100272438; called by muse, mutect2, varscan2
- NABP1 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100322951; called by muse, mutect2, varscan2
- NALCN | c.4364C>T p.S1455F | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51915119, COSV51937478; called by muse, mutect2, varscan2
- NAT10 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as rs756436278, COSV99139892; called by muse, mutect2, varscan2
- NBAS | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99866581; called by muse, mutect2, varscan2
- NBEA | c.6686T>A p.V2229E | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV100075871, COSV59782013; called by muse, mutect2, varscan2
- NBEAL1 | c.6045T>G p.F2015L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs576030684, COSV101355348; called by muse, mutect2, varscan2
- NBPF9 | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs782098985; called by muse, mutect2, varscan2
- NDST4 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs866291626, COSV52109617; called by muse, mutect2, varscan2
- NDUFAF6 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs1430891827, COSV99712554; called by muse, mutect2, varscan2
- NDUFS8 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as rs569695304, COSV55836730; called by muse, mutect2, varscan2
- NEFH | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.109); catalogued as COSV100151157; called by muse, mutect2, varscan2
- NEU2 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs759911096, COSV52092528; called by muse, mutect2, varscan2
- NEURL1 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as COSV100872605; called by muse, mutect2, varscan2
- NEXMIF | c.3851C>T p.A1284V | Missense Mutation (SNP) | VAF 30/33 reads (91%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV50047875; called by muse, mutect2, varscan2
- NEXMIF | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV99279333; called by muse, mutect2, varscan2
- NFATC4 | c.2603G>A p.R868Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.294); catalogued as rs779626056, COSV99144219; called by muse, mutect2, varscan2
- NGEF | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.137); catalogued as rs1476763046, COSV99887702; called by muse, mutect2, varscan2
- NIBAN2 | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs776632695, COSV64823707; called by muse, mutect2, varscan2
- NIM1K | c.1234A>T p.K412* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100389818; called by muse, mutect2, varscan2
- NIPBL | c.6559G>A p.E2187K | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as COSV56972309, COSV99238291; called by muse, mutect2, varscan2
- NKAPL | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs765647481, COSV100642437; called by muse, mutect2
- NLGN4Y | c.2184G>C p.E728D | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.665); catalogued as COSV100196240; called by muse, mutect2, varscan2
- NLRP13 | c.2473G>A p.A825T | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs1221817206, COSV100737943; called by muse, mutect2, varscan2
- NLRP3 | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV100275077, COSV60225287; called by muse, mutect2, varscan2
- NLRP7 | c.1256C>A p.A419D | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100051435, COSV60178815; called by muse, mutect2, varscan2
- NLRP9 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs747911398, COSV60461087, COSV60465744; called by muse, varscan2
- NOTCH1 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.938); catalogued as COSV53053163; called by muse, varscan2
- NOTCH1 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as COSV53057433; called by muse, varscan2
- NOTCH4 | c.3409C>T p.P1137S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.056); catalogued as COSV100900281; called by muse, mutect2, varscan2
- NOTCH4 | c.1826G>A p.G609E | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as COSV100900284, COSV66680438; called by muse, mutect2, varscan2
- NPAP1 | c.3384G>A p.W1128* | Nonsense Mutation (SNP) | VAF 43/123 reads (35%) | catalogued as COSV61508450; called by muse, mutect2, varscan2
- NPAS4 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV100214706; called by muse, mutect2, varscan2
- NPAS4 | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV100214708; called by muse, mutect2, varscan2
- NRCAM | c.1120C>T p.P374S (on ENST00000379028 / NM_001371124.1; = p.P368S on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs756712715, COSV61037468; called by muse, mutect2, varscan2
- NUP210 | c.1858C>T p.L620F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs1337056940, COSV99595370; called by muse, mutect2, varscan2
- NUP98 | c.5093G>A p.R1698K (on ENST00000359171 / NM_001365126.1; = p.R1681K on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV100261375; called by muse, mutect2, varscan2
- NXPH3 | c.469T>C p.F157L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as COSV100165433; called by muse, mutect2, varscan2
- OASL | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as rs1382116265, COSV99984374; called by muse, mutect2, varscan2
- OBSCN | c.6784G>A p.V2262I | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.978); catalogued as COSV52813738, COSV99474782; called by muse, mutect2, varscan2
- OBSCN | c.17749G>A p.G5917S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV99471056; called by muse, mutect2, varscan2
- OBSCN | c.19576G>A p.G6526R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100800333, COSV100803078; called by muse, mutect2, varscan2
- OLFM2 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV53432361; called by muse, mutect2, varscan2
- OPN3 | c.447C>G p.I149M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as COSV100086915; called by muse, varscan2
- OR10G4 | c.623G>A p.G208D | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); catalogued as rs201229870, COSV100304652, COSV57979297; called by muse, mutect2, varscan2
- OR10H1 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs939055536, COSV100612331; called by muse, mutect2, varscan2
- OR11H12 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV101612446; called by mutect2, varscan2
- OR11H6 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs367798181; called by muse, mutect2, varscan2
- OR11L1 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100869372; called by muse, mutect2, varscan2
- OR12D3 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745630094, COSV65827079; called by muse, mutect2, varscan2
- OR1D2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV58921245; called by muse, mutect2, varscan2
- OR2A12 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.384); catalogued as rs267601374, COSV68821949; called by muse, mutect2, varscan2
- OR2AG2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as COSV100643045; called by muse, mutect2, varscan2
- OR2G2 | c.276G>A p.M92I | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs866761315, COSV60739287; called by muse, mutect2, varscan2
- OR2G6 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58574321; called by muse, mutect2, varscan2
- OR2M5 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.32); catalogued as COSV100822710; called by muse, mutect2, varscan2
- OR4C15 | c.523C>T p.R175C (on ENST00000314644; = p.R121C on NM_001001920.2) | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as rs267602969, COSV58951118, COSV58951281; called by muse, mutect2, varscan2
- OR4C3 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60584139, COSV60585481; called by muse, mutect2, varscan2
- OR4C46 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV60221146, COSV60221672; called by muse, mutect2, varscan2
- OR4C6 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs758144921, COSV100051329; called by muse, mutect2, varscan2
- OR4K17 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV59648225; called by muse, mutect2, varscan2
- OR4K17 | c.635T>A p.I212N | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV100210441; called by muse, mutect2, varscan2
- OR4K2 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100063945; called by muse, mutect2, varscan2
- OR51A2 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100984987; called by muse, mutect2, varscan2
- OR51A4 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.694); catalogued as COSV66749959; called by muse, varscan2
- OR51E2 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs767765213, COSV67808398; called by mutect2, varscan2
- OR51V1 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs754936531, COSV100343113; called by muse, mutect2, varscan2
- OR52N1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100398576; called by muse, mutect2, varscan2
- OR52R1 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100617561; called by muse, mutect2, varscan2
- OR5B17 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.012); catalogued as COSV100641837, COSV100641907; called by muse, mutect2, varscan2
- OR5L1 | c.414G>A p.W138* | Nonsense Mutation (SNP) | VAF 48/145 reads (33%) | catalogued as COSV100449873; called by muse, mutect2, varscan2
- OR5M8 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV59115605; called by muse, mutect2, varscan2
- OR5T2 | c.821G>A p.R274K | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV57589950; called by muse, mutect2, varscan2
- OR6B1 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs752940401, COSV68769870, COSV68770350; called by muse, mutect2, varscan2
- OR6C65 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as COSV65568338; called by muse, mutect2, varscan2
- OR6M1 | c.896G>A p.R299K | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0.052); catalogued as COSV58433577; called by muse, mutect2, varscan2
- OR6N1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV58648016; called by muse, mutect2, varscan2
- OR7D4 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV58072224; called by muse, mutect2, varscan2
- OR8H2 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57943616; called by muse, mutect2, varscan2
- OR8I2 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.396); catalogued as COSV100135793; called by muse, mutect2, varscan2
- OR8K3 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.337); catalogued as COSV57130668, COSV57131689; called by muse, mutect2
- OR9A2 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317248278, COSV63306532; called by muse, varscan2
- OR9A4 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV101516324, COSV71885127; called by muse, mutect2, varscan2
- OR9K2 | c.683C>T p.S228L (on ENST00000305377; = p.S206L on NM_001005243.1) | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.41); catalogued as rs368474784; called by muse, mutect2, varscan2
- ORAI3 | c.761C>A p.P254H | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52691817; called by muse, mutect2, varscan2
- OSBPL8 | c.780G>T p.L260F | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99674315; called by muse, mutect2, varscan2
- OTOP2 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 110/191 reads (58%) | SIFT tolerated (0.82); PolyPhen benign (0.013); catalogued as rs1342273019, COSV58880379; called by muse, mutect2, varscan2
- OXGR1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.501); catalogued as COSV100036853; called by muse, mutect2, varscan2
- P2RY14 | c.587G>A p.W196* | Nonsense Mutation (SNP) | VAF 38/81 reads (47%) | catalogued as rs1430428990, COSV99851100; called by muse, mutect2, varscan2
- P3H2 | c.1664C>T p.S555F | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV60020194; called by muse, mutect2, varscan2
- PABPC3 | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV99878896; called by muse, mutect2, varscan2
- PACS1 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV57697743; called by muse, mutect2, varscan2
- PACS2 | c.1723A>G p.T575A | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV100330555; called by muse, mutect2, varscan2
- PAK5 | c.1885C>T p.L629F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV62030872; called by muse, mutect2, varscan2
- PALB2 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV99847907; called by muse, mutect2, varscan2
- PAPOLB | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.661); catalogued as COSV68201666; called by muse, mutect2, varscan2
- PAPPA | c.4776+1G>A p.X1592_splice | Splice Site (SNP) | VAF 23/50 reads (46%) | catalogued as COSV100072600, COSV60289149; called by muse, mutect2, varscan2
- PARD3 | c.3202C>T p.R1068* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV61056190; called by muse, mutect2, varscan2
- PARD6G | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100783295; called by muse, mutect2
- PAX3 | c.1410G>C p.Q470H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100398887, COSV60592558; called by muse, mutect2, varscan2
- PCDH11X | c.3307C>T p.R1103C | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100007195; called by muse, mutect2, varscan2
- PCDH12 | c.2657C>A p.P886H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV99185727; called by mutect2, varscan2
- PCDH15 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100213566; called by muse, mutect2, varscan2
- PCDH18 | c.2661G>T p.L887F | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.312); catalogued as COSV100786932; called by muse, mutect2, varscan2
- PCDHA13 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as COSV56515960; called by muse, mutect2, varscan2
- PCDHA4 | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 51/145 reads (35%) | catalogued as COSV100793088; called by muse, mutect2, varscan2
- PCDHB3 | c.202T>A p.S68T | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.472); catalogued as COSV99164093; called by muse, mutect2, varscan2
- PCDHB8 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1488040699, COSV99175240; called by muse, mutect2, varscan2
- PCDHB8 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 75/202 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); catalogued as COSV50795656; called by muse, mutect2, varscan2
- PCID2 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55813547; called by muse, mutect2, varscan2
- PCLO | c.9539C>T p.S3180F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.406); catalogued as COSV100426392, COSV61633072; called by muse, mutect2, varscan2
- PCLO | c.2909C>T p.P970L | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV100426401; called by muse, mutect2, varscan2
- PCMTD2 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55060393, COSV55060824; called by muse, mutect2, varscan2
- PCNX2 | c.3833G>A p.S1278N | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV50786454, COSV99265564; called by muse, mutect2, varscan2
- PDE1C | c.1379C>A p.T460N | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV100370490; called by muse, mutect2, varscan2
- PDLIM4 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as rs371212671; called by muse, mutect2, varscan2
- PFAS | c.3784G>A p.D1262N | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58981514; called by muse, mutect2, varscan2
- PGAM2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs368147620; called by muse, mutect2, varscan2
- PICK1 | c.1051G>T p.V351L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.037); catalogued as COSV100259879, COSV57636939; called by muse, mutect2, varscan2
- PIGR | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100732412; called by muse, mutect2, varscan2
- PIK3C2A | c.1398T>A p.D466E | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99790084; called by muse, mutect2, varscan2
- PKD1L1 | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as COSV99218021; called by muse, mutect2, varscan2
- PKHD1L1 | c.4658C>T p.S1553L | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs372148502, COSV101005104; called by muse, mutect2, varscan2
1,036 further variants in this file (416 protein-altering or splice-affecting, 585 silent, 35 other) are not listed here.
